Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ACXF, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ACXF-TTP1-A (Primary Tumor).

[page 1 of 14]
9671 Exceptional responders

ANATOMIC PATHOLOGY

[REDACTED]
[REDACTED]
[REDACTED]

Sex: Female

Location: [REDACTED]
Collected: [REDACTED] +0
Received: [REDACTED] +0
Printed: [REDACTED]
Order Physician: [REDACTED]
Copy To: [REDACTED]
Admit Physician: [REDACTED]

SURGICAL PATHOLOGY FINAL REPORT

PATHOLOGY NO:

Diagnosis

A. Brain, biopsy for frozen section
- anaplastic astrocytoma (Grade III/IV).

B. Brain, biopsy for permanent sections
- anaplastic astrocytoma (Grade III/IV).

REV: [REDACTED]

Pathologist Comment

The tumor is positive for GFAP and S100 and shows a high mib-1 labelling fraction. It is negative for AE1/AE3. Frequent mitoses, including atypical mitoses, are present. There is significant cellular pleomorphism. Necrosis is not identified.

Clinical Information

[REDACTED] woman who presented with headaches. MRI showed a 3.8 x 3.7 x 2.7 cm lesion between the frontal horns of both lateral ventricles. Clinical diagnosis for this third ventricle tumor included possible low grade glioma or possible neurocytoma.

Specimen Source

- A Brain, Biopsy for FROZEN SECTION
- B Brain, Biopsy for PERMANENT SECTIONS

Microscopic Description

Microscopic examination was performed.

Gross Description

Part A. Received fresh labelled [REDACTED] #1 brain tumor" are three pieces of soft tan-white tissue, measuring 1.5, 1.5, and less than 1 mm. Touch preparations are made, and the tissue is submitted entirely for frozen section.

[page 2 of 14]
9671 Exceptional responders

ANATOMIC PATHOLOGY

N
E
P
A
B.

Sex: Female

Location: [REDACTED]
Collected: [REDACTED] +0
Received: [REDACTED] +0
Printed: [REDACTED]
Order Physician: [REDACTED]
Copy To: [REDACTED]
Admit Physician: [REDACTED]

SURGICAL PATHOLOGY FINAL REPORT

PATHOLOGY NO:
[REDACTED]

Frozen section diagnosis: Cellular glial neoplasm with pleomorphic cells, rare mitosis, no necrosis identified. Favor a high grade glial neoplasm. REV: [REDACTED]

Submitted for permanent sections labelled A1.

Part B. Submitted in a container of formalin labelled [REDACTED] - #2 more brain tumor" is an aggregate of pinkish-tan soft tissue measuring 0.4 x 0.4 x 0.1 cm. The specimen is submitted entirely in B1. [REDACTED]

Additional Comment

IMMUNOHISTOCHEMISTRY

The performance characteristics of all immunohistochemical stains cited in this report were determined by the [REDACTED] compliance with CLIA'88 regulations. Some of these tests rely on the use of "analyte specific reagents" and are subject to specific labeling requirements by the FDA.

This testing was developed by the [REDACTED] It has not been cleared or approved by the FDA. The FDA has determined that such clearance or approval is not necessary.

SURGICAL PATHOLOGY ADDENDUM REPORT

PATHOLOGY NO:
[REDACTED]

Discussion

This case was sent to [REDACTED] for review on [REDACTED] +239

[page 3 of 14]
9671 Exceptional responders

*****TOMIC PATHOLOGY

Sex: female

Location:
Collected:
Received:
Printed:
Order Physician:
Copy To:
Admit Physician:

+0
+0

SURGICAL PATHOLOGY ADDENDUM REPORT

PATHOLOGY NO:

Diagnosis

Please see their report.

[page 4 of 14]
SURGICAL PATHOLOGY REPORT *** Consult Report ***

FINAL

9671 Exceptional responders

DOB: [REDACTED]

Physician(s): [REDACTED]

Service:
Location:
MRN:
Hospital #:
Patient Type:

Inside/Outside

Accession #:
Y-axis:
Resected:
Accepted:
Reported:

+239

DIAGNOSIS

OUTSIDE CONSULT MATERIAL FROM [REDACTED] +0
BRAIN, SITE NOT SPECIFIED, BIOPSY
-GLIOBLASTOMA, WHO GRADE IV (SEE COMMENT)

Microscopic Description and Comment:

Permanent sections submitted by [REDACTED] Department of Pathology shows a high-grade infiltrating astrocytic neoplasm composed of small cells with bipolar nuclei and large pleomorphic cells with irregular hyperchromatic nuclei, and increased mitotic activity. Microvascular proliferation is focally present and there is equivocal necrosis. Immunohistochemical staining for glial fibrillary acidic protein (GFAP), and MIB-1 (KI-67) was performed. GFAP staining shows immunoreactivity within the tumor, highlighting many of the larger cells. MIB-1 (KI-67) proliferative index is high. In addition, G100 shows diffuse staining while a cytokeratin AE1/AE3 is essentially negative.

Based on histomorphological features and immunostaining profile this neoplasm is consistent with a glioblastoma, WHO grade IV.

History:

The patient is a [REDACTED] woman who reportedly "presented with headaches. MRI showed a 3.8x3.7x2.7cm lesion

[page 5 of 14]
SURGICAL PATHOLOGY REPORT

between the frontal horns of both lateral ventricles that shows some contrast enhancement."

Materials Received:

Received are eleven slides labeled [redacted] and sublabeled A and B. These slides are derived from a brain, biopsy +0 for frozen section (A) and a brain, biopsy for permanent sections (B) performed on [redacted] as detailed in the accompanying corresponding pathology report. The material originates from [redacted]

END OF REPORT

Page 2 of 2

[page 6 of 14]
MRI BRAIN W WO CONTRAST

Status: Final
result

-11

Results

Patient Information

Patient Name

Sex

DOB

Female

Exam Information

Status

Exam
BegunExam
Ended

Final

Study Result

Multiplanar imaging of the brain was performed with and without IV gadolinium. 20 mL of Magnevist were given.

Pituitary gland is unremarkable. The diffusion-weighted images show no acute ischemic changes. Normal major intracranial vessels are present. Paranasal sinuses are clear. There is a well described lesion situated between the frontal horns of both lateral ventricles. This probably is interventricular in location and appears midline in origin, possibly arising from the septum pellucidum.

Appearance of the lesion is heterogeneous with low signal on all sequences that suggests flow-voids. Correlation with CT indicates that these do not appear to represent calcifications. Postcontrast images show mild enhancement. No other lesions are seen. There is mild edema surrounding this lesion. Mild hydrocephalus is present. The mass measures approximately 3.8 cm in height x 2.7 cm in AP dimension x 3.7 cm in width.

The brain MRA shows patency of the distal vertebral arteries and basilar artery. The intracranial internal carotid arteries are patent bilaterally. The anterior, middle and posterior cerebral arteries are patent. No aneurysm or significant focal stenosis is identified.

Impression:

1. Moderate sized lesion situated between the frontal horns of both lateral ventricles which causes mild hydrocephalus. Strong considerations include a central neurocytoma and a subependymoma. A meningioma and choroid plexus papilloma and metastasis are considered unlikely.

2. Brain MRA shows no significant abnormality.

Result History

Radiology Order Result History

[page 7 of 14]
MRI BRAIN W WO CONTRAST (Accession Number**(Order****Status: Final
result****Results**

+684

Patient Information

Patient Name

Sex

DOB

Female

Exam Information

Status

Exam

Begun +684

Exam

Ended +684

Final

Study Result

Multipolar imaging of the brain was performed with and without IV gadolinium.

History is malignant neoplasm of the frontal lobe of the brain. 20 ml of Optmark were given.

Comparison is made to previous exam from +565

Pituitary gland is unremarkable. There is a surgical defect in the body of the corpus callosum. There are also postop change of a right sided craniotomy. The diffusion weighted images show no acute ischemic changes. FLAIR images redemonstrate high-signal-intensity in the subcortical deep and white matter of anterior right frontal lobe as well as the medial aspects of both frontal lobes. This has not changed since the previous exam. This is felt to be due to gliosis as well as probably radiation change. Clinical correlation is needed. The postcontrast images are stable. No new lesion enhancement is seen. Small bilateral areas of enhancement along the anterior aspects of the lateral ventricles are again seen and stable. Ventricles are not enlarged. No new findings are seen. Major intracranial flow-voids remain. Paranasal sinuses are clear.

IMPRESSION

Impression: Stable exam, no new findings or recurrent lesion is seen.

+684

Result History

Radiology Order Result History

PACS Images

Show images for MRI BRAIN W WO CONTRAST

External Results Report

Open External Results Report

Link(s) to Patient Summary Reports

Rad Invasive Timeline

Associated Diagnoses

9671 Exceptional responders

[page 8 of 14]
MRI BRAIN W WO CONTRAST (Accession NumberStatus: Final
result:**Results**

+217

Patient Information

Patient Name

Sex

DOB

Female

Exam Information

Status

Exam
BegunExam
Ended

Final

+217

Study Result

The study is compared with the previous exam dated +119

18 mL of Optiray contrast were given during the exam. Craniotomy changes are seen along the vertex on the right. Atrophy of the anterior body of the corpus callosum is noted on the sagittal images. No extra-axial fluid collections or masses are seen around the convexities.

The posterior fossa appears normal. The ventricles are unremarkable.

FLAIR images show abnormal signal in the rostrum of corpus callosum, and to a small degree in the right forceps minor and the cingulate gyrus. Some signal is present in the right hypothalamic region.

No sites of restricted diffusion are appreciated.

Postcontrast images show enhancement in the corpus callosum and adjacent forceps minor on the right. +119

Compared with the prior exam of the amount of enhancing tissue has increased perhaps 50% in size. The margins are rather irregular and poorly defined. The amount of surrounding edema is slightly decreased.

Impression:

1. A mild increase in the amount of enhancing tissue is present at the operative site, probably reflecting residual neoplasm. Mild decrease in the amount of surrounding edema is present.

Result History

Radiology Order Result History

External Results Report

Open External Results Report

Link(s) to Patient Summary Reports

Rad Invasive Timeline

9671 Exceptional responders

[page 9 of 14]
9671 Exceptional responders

IMAGING SERVICES

Exam Date/Time:	+3780	Phone #:	MRN:
Sex:	Female	Account #:	
Pt. Class:	Outpatient	Accession #:	Performing Department:
Primary Care Provider:	Ordering Provider:	Authorizing Provider:	

Final - MRI BRAIN W WO CONTRAST

Reason for Exam:

Diagnosis: Glioblastoma
Proteinuria, unspecified type
Polycythemia

INTERPRETATION

IMPRESSION: Please see below.

Exam: MRI BRAIN W WO CONTRAST

Date/Time of Exam: +3780

Reason For Exam: Glioblastoma, proteinuria, unspecified type, Polycythemia.

Technique: MRI of the brain was performed prior to and following the administration of intravenous contrast.

Contrast: 20 mL of MultiHance.

Comparison: Brain MRI +3409

Findings: Stable appearance of the left anterior frontal paramedian resection cavity involving the portion of the body of the corpus callosum and adjacent bifrontal encephalomalacia and suspected gliosis, greater on the right. Right anterior superior frontal craniotomy. No new areas of abnormal signal or enhancement. No hydrocephalus or midline shift.

IMPRESSION:

1. Stable post-treatment changes and bifrontal encephalomalacia and gliosis.

+3780

+3780

D:

T:

[page 10 of 14]
[REDACTED]

9671 Exceptional responders

[REDACTED]

[REDACTED]

[page 11 of 14]
BL imaging = Day 0

[page 12 of 14]
GBM (anaplastic astrocytoma). MRI, axial coronal and sagittal images, various sequences. (Arrows and measurements on next slide)

BL = Day 0 (Left column), original tumor

BL + 8 months (2nd column) = Day 217, Post op and post therapy.

BL + 23 months (both RT columns) = Day 684
Post op and post therapy

Level 1 case

[page 13 of 14]
Level 1 case

GBM (anaplastic astrocytoma)

MRI: axial, coronal and sagittal images, various sequences.

BL = Day 0 (Left column), original tumor 34 x 27 x 30 mm (wide arrows)

BL + 8 months (2nd column) = Day 217, Post op and post therapy. 16 x 20 x 22 mm at areas of enhancement (thin red arrows at areas of enhancement)

BL + 23 months (both RT columns) = Day 684 Post op and post therapy. Various areas of enhancement 5 to 18 mm in length

[page 14 of 14]
ICD-0-3

CQCF: astrocytoma, NOS 9400/3
Path: glioblastoma, NOS 9440/3
Site: brain, NOS C71.9

SURGICAL PATHOLOGY REPORT

*** Consult Report ***

ICD-10

C71.9

hw
3/8/14

FINAL

DOB: [REDACTED]

Physician(s):

DIAGNOSIS

OUTSIDE CONSULT MATERIAL FROM
BRAIN, SITE NOT SPECIFIED, BIOPSY
-GLIOBLASTOMA, WHO GRADE IV (SEE COMMENT)

By the signature, I attest that the above diagnosis is based upon my personal
examination of the slides and/or other material included in the request.

***Report Electronically Reviewed and Signed Off By: [REDACTED]

Microscopic Description and Comment:

Permanent sections submitted by [REDACTED] shows a high-grade infiltrating astrocytic neoplasm composed of small cells with bipolar nuclei and large pleomorphic cells with irregular hyperchromatic nuclei, and increased mitotic activity. Microvascular proliferation is focally present and there is equivocal necrosis. Immunohistochemical staining for glial fibrillary acidic protein (GFAP), and MIB-1 (Ki-67) was performed. GFAP staining shows immunoreactivity within the tumor, highlighting many of the larger cells. MIB-1 (Ki-67) proliferative index is high. In addition, S100 shows diffuse staining while a cytokeratin AE1/AE3 is essentially negative.

Based on histomorphological features and immunostaining profile this neoplasm is consistent with a glioblastoma, WHO grade IV.

History:

The patient is a

woman who reportedly presented with headaches. MRI showed a 3.8x3.7x2.7cm lesion

Source: NCI Genomic Data Commons file 1e804816-a727-4483-8fbd-e7506e7d2c60 (ER0256 ER-ACXF Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).